Somatic mutation profile of tumor specimen TCGA-L5-A4OF-01A (aliquot TCGA-L5-A4OF-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OF, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.5 years (23,194 days).
Specimen TCGA-L5-A4OF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9d33c82-ca0a-4414-864f-1db31cf07375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OF-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OF-11A-12D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78c261e2-a6cd-4d1a-9278-9f8159e5b0ff

The open-access MAF lists 82 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 54, Silent 18, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.764_766del p.I255del | In Frame Del (DEL) | VAF 87/189 reads (46%) | hotspot (GDC flag); catalogued as rs1064794309; called by pindel, varscan2
- ACACB | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs781314104, COSV58142237; called by muse, mutect2, varscan2
- ACE | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs546455400; called by muse, mutect2, varscan2
- ASXL3 | c.3565A>G p.S1189G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs761866641, COSV99036122; called by muse, mutect2
- ATP2C1 | c.1067C>A p.T356K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD128760, COSV100146699; called by muse, mutect2
- C6orf118 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs1257110834, COSV57817906; called by muse, mutect2, varscan2
- CCDC88A | c.4990C>G p.L1664V (on ENST00000436346 / NM_001365480.1; = p.L1636V on NM_018084.5) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs764420887; called by muse, mutect2, varscan2
- CCM2L | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769382467, COSV52949977; called by muse, mutect2, varscan2
- CUL5 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101263670; called by muse, mutect2, varscan2
- DCLRE1C | c.1804T>C p.Y602H (on ENST00000378278 / NM_001350965.2; = p.Y487H on NM_022487.4) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1339921043; called by muse, mutect2, varscan2
- FUT6 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.038); catalogued as COSV54608048; called by muse, mutect2, varscan2
- ITPRIP | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs966846222; called by muse, mutect2
- KCTD1 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200587071, COSV58685359; called by muse, mutect2, varscan2
- KREMEN1 | c.757C>T p.H253Y (on ENST00000407188; = p.H255Y on NM_032045.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.212); catalogued as COSV59914451; called by muse, mutect2, varscan2
- LRP3 | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs149990905; called by muse, mutect2, varscan2
- MYB | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57202105; called by muse, mutect2, varscan2
- NEB | c.19220G>A p.R6407Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs745615279, COSV51441238, COSV51460697; called by muse, mutect2, varscan2
- NETO1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as rs750903661, COSV55013043; called by muse, mutect2, varscan2
- NOTCH4 | c.4210G>A p.D1404N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.102); catalogued as COSV66680381; called by muse, mutect2, varscan2
- OPA3 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs758982194; called by muse, varscan2
- PNPLA6 | c.964C>T p.R322W (on ENST00000414982 / NM_001166111.2; = p.R274W on NM_006702.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99654085; called by muse, mutect2, varscan2
- POLL | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs202232099; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as rs759673217; called by muse, mutect2, varscan2
- RASAL3 | c.2821C>G p.R941G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs371247954; called by muse, mutect2, varscan2
- SEMA6D | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100317525; called by muse, mutect2, varscan2
- SENP7 | c.2480+1G>A p.X827_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as rs1316113359, COSV100053526; called by muse, mutect2, varscan2
- SYNE1 | c.13079C>A p.A4360E (on ENST00000367255 / NM_182961.4; = p.A4289E on NM_033071.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99572939; called by muse, mutect2
- TENM4 | c.5495G>A p.R1832Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs780208260; called by muse, mutect2, varscan2
- VSX2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886042716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZMYM1 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as rs1336672595; called by muse, mutect2
- ADH1C | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALG10 | c.1034A>T p.K345I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- AP3B2 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ARHGAP5 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2A3 | c.2511C>A p.Y837* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- BRD7 | c.1346del p.L449Wfs*19 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | called by mutect2, pindel, varscan2
- CCDC146 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DDRGK1 | c.600G>C p.E200D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DHRS4 | c.479+2T>C p.X160_splice | Splice Site (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- EML5 | c.5907C>A p.H1969Q (on ENST00000380664; = p.H1977Q on NM_183387.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- F8 | c.3373G>C p.A1125P | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FHIT | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- FRY | c.409_413del p.G137* | Frame Shift Del (DEL) | VAF 30/57 reads (53%) | called by mutect2, pindel, varscan2
- GK2 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRPR | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGF | c.2155del p.I719Lfs*3 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- MICAL1 | c.2909G>A p.W970* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- NELL2 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- OR1J2 | c.638G>C p.C213S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- OR2D3 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- OR4L1 | c.683A>T p.K228I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PATL1 | c.2211C>G p.I737M | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- PCM1 | c.2134A>C p.N712H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RIMS1 | c.4908G>A p.M1636I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RYR3 | c.5454G>C p.E1818D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCG5 | c.526G>A p.E176K (on ENST00000300175 / NM_001144757.2; = p.E175K on NM_003020.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SH3GL3 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SLC17A6 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC17A9 | c.404A>C p.Y135S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- TMEM132A | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- WNK1 | c.4934A>G p.K1645R (on ENST00000315939 / NM_018979.4; = p.K1398R on NM_014823.3) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFP64 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP64 | c.1014G>T p.Q338H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF778 | c.1711A>T p.T571S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.218); called by muse, mutect2
- BAZ1B | c.4416C>T p.A1472= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1256786997, COSV100290240, COSV59989406; called by muse, mutect2, varscan2
- BBS7 | c.453C>A p.I151= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- CDH22 | c.2061G>A p.A687= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- DCAF4L1 | c.783G>C p.G261= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- ECRG4 | c.156C>T p.A52= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs962297240, COSV53002063, COSV99430276; called by muse, mutect2, varscan2
- GNL1 | c.1533C>T p.D511= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs749324764; called by muse, mutect2, varscan2
- IGKV1D-17 | c.324T>C p.Y108= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs762386543; called by muse, mutect2, varscan2
- IL20RB | c.177G>A p.A59= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs959336573, COSV100291273; called by muse, mutect2, varscan2
- LRRTM4 | c.690C>T p.N230= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV69142947; called by muse, mutect2, varscan2
- MEGF8 | c.1308G>T p.L436= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV99236506; called by muse, mutect2, varscan2
- MIXL1 | c.675C>A p.I225= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- OLFML1 | c.27T>C p.S9= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as rs1324184725; called by muse, mutect2
- OR2T11 | c.6G>A p.T2= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs200548184; called by muse, mutect2, varscan2
- PARD3 | c.1482C>T p.L494= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1199413841, COSV60750832, COSV60755101; called by muse, mutect2, varscan2
- PIGW | c.117G>A p.L39= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- TG | c.3255G>T p.L1085= | Silent (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- UGGT1 | c.3786A>G p.A1262= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- ZNF106 | c.4566C>A p.P1522= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
